Somatic mutation profile of tumor specimen TCGA-CN-5358-01A (aliquot TCGA-CN-5358-01A-01D-1512-08) from TCGA case TCGA-CN-5358, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.6 years (22,138 days).
Specimen TCGA-CN-5358-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cede55b2-e382-4105-a9cc-8ab7b5cf9008.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5358-10A (Blood Derived Normal), aliquot TCGA-CN-5358-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68043b59-1fe6-4088-84a0-a6e674ca6bee

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Nonsense Mutation 4, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.626_627del p.R209Kfs*6 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | catalogued as rs1057517840; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANK2 | c.10123C>G p.Q3375E | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.121); catalogued as COSV52161161; called by muse, mutect2
- CACNG8 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); catalogued as COSV99554995; called by muse, mutect2
- CMTR2 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100579155, COSV57604673; called by muse, mutect2, varscan2
- DHX30 | c.464G>A p.R155H (on ENST00000445061 / NM_138615.3; = p.R116H on NM_014966.3) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.232); catalogued as rs139889547; called by muse, mutect2, varscan2
- DPY19L3 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100639154; called by muse, mutect2
- ESR1 | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99239194; called by muse, mutect2
- GLUL | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100091990; called by muse, mutect2
- GNE | c.1298A>G p.H433R (on ENST00000396594 / NM_001128227.3; = p.H402R on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV100929976; called by muse, mutect2
- JAK1 | c.2572G>C p.E858Q | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV61097649; called by muse, mutect2, varscan2
- KMT2A | c.11182G>T p.V3728L | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs781822608, COSV100628843; called by muse, mutect2
- NEURL2 | c.415C>G p.P139A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51940301, COSV99509864; called by muse, mutect2
- NISCH | c.555T>G p.C185W | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100617334; called by muse, mutect2
- OR4D2 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101613857, COSV73459777; called by muse, mutect2
- PCDHGB2 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV99538386; called by muse, mutect2
- PCLO | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100432692; called by muse, mutect2
- PHF3 | c.4021C>G p.L1341V | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100013359, COSV50312875; called by muse, mutect2
- PPP2R2D | c.1103A>G p.Y368C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101409046; called by muse, mutect2, varscan2
- RICTOR | c.4897G>T p.E1633* | Nonsense Mutation (SNP) | VAF 10/263 reads (4%) | catalogued as COSV57118660, COSV57132441, COSV99705219; called by muse, mutect2
- RNASE11 | c.474C>A p.C158* | Nonsense Mutation (SNP) | VAF 9/107 reads (8%) | catalogued as rs1447923075, COSV100250524, COSV60087354; called by muse, mutect2
- SAMD9L | c.4053C>A p.Y1351* | Nonsense Mutation (SNP) | VAF 43/285 reads (15%) | catalogued as COSV100560694; called by muse, mutect2, varscan2
- UGT1A8 | c.805A>G p.M269V | Missense Mutation (SNP) | VAF 36/490 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs748414290, COSV100990622; called by muse, mutect2
- USP9X | c.1109A>G p.H370R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100199279; called by muse, mutect2, varscan2
- ZNF676 | c.793G>A p.A265T (on ENST00000650058; = p.A233T on NM_001001411.3) | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as rs1420613245, COSV101236214; called by muse, mutect2
- ZNF804B | c.2392A>T p.K798* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100303813; called by muse, mutect2, varscan2
- PITX1 | c.837C>G p.N279K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ACTG1 | c.834C>A p.T278= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as COSV100111934; called by muse, mutect2
- ANK2 | c.9675C>T p.L3225= | Silent (SNP) | VAF 11/132 reads (8%) | catalogued as rs764297357, COSV100001666; called by muse, mutect2
- CPLX1 | c.36C>T p.A12= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as rs769372085, COSV100408289; called by muse, mutect2, varscan2
- DNAH3 | c.1386C>T p.S462= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV99767487; called by muse, mutect2
- HTR1D | c.111C>G p.L37= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as COSV100024875; called by muse, mutect2
- RAET1G | c.450C>G p.L150= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as rs1262983037, COSV100951666; called by muse, mutect2
- TBC1D1 | c.3426G>A p.T1142= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs375379532; called by muse, mutect2
- TTN | c.69828C>G p.V23276= (on ENST00000591111; = p.V15852= on NM_003319.4) | Silent (SNP) | VAF 6/180 reads (3%) | catalogued as COSV100612780; called by muse, mutect2
- MIR924 | n.9C>T | RNA (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
